Gene-level copy-number profile of tumor specimen TCGA-2G-AAHM-01A from TCGA case TCGA-2G-AAHM, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Dead; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 33.2 years (12,110 days).
Specimen TCGA-2G-AAHM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ff4925db-bb56-4418-ad94-9701707a17f3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAHM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/65f67cfb-d3d6-44ef-acbf-df8488a1946b

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 1,460; copy number 3: 13,080; copy number 4: 9,186; copy number 5: 17,405; copy number 6: 11,403; copy number 7: 4,610; copy number 8: 1,327; copy number 9: 102; copy number 10: 115; copy number 11: 141; copy number 12: 76; copy number 15: 2; copy number 16: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 220 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:51,257,688–58,272,450, 111 genes, copy number 11–12 (broad region; genes not listed).
- chr16:32,356,981–32,380,049, 2 genes, copy number 15: AC133548.1, ACTR3BP3.
- chr16:32,439,069–32,441,159, 1 gene, copy number 16: PABPC1P13.
- chr18:10,124,588–13,652,755, 106 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
